Somatic mutation profile of tumor specimen MMRF_1077_1_BM_CD138pos (aliquot MMRF_1077_1_BM_CD138pos_T2_TSE61_K02706) from MMRF case MMRF_1077, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.7 years (24,743 days).
Specimen MMRF_1077_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db1befb3-bf27-4a9b-9af2-40e8548cb0e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1077_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1077_1_PB_Whole_C1_TSE61_K02713; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2849e87c-79d4-47b0-ab48-039708e53af8

The open-access MAF lists 83 somatic variants for this specimen: 30 protein-altering or splice-affecting, 13 silent, 40 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 29, Missense Mutation 28, Silent 13, RNA 4, 5'UTR 3, 3'Flank 2, Frame Shift Ins 1, 5'Flank 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATF6 | c.954A>C p.E318D | Missense Mutation (SNP) | VAF 55/156 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV63410589; called by muse, mutect2, varscan2
- CNTN6 | c.515G>T p.R172L | Missense Mutation (SNP) | VAF 69/117 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as COSV63172416; called by muse, mutect2, varscan2
- GABRP | c.82G>A p.V28I | Missense Mutation (SNP) | VAF 104/158 reads (66%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs145941447; called by muse, mutect2, varscan2
- LRBA | c.6428C>T p.S2143F | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1326530234, COSV63965648; called by muse, mutect2, varscan2
- PALLD | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 55/99 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs138665337; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- STXBP5L | c.2168G>A p.R723H | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.987); catalogued as rs750739021, COSV56512660; called by muse, mutect2, varscan2
- TPCN2 | c.683G>A p.C228Y | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as rs892711998; called by muse, mutect2, varscan2
- ZNF516 | c.1621C>T p.R541C | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.828); catalogued as rs572186968, COSV71586924; called by muse, mutect2, varscan2
- ZNF521 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs999285894, COSV64132966; called by muse, mutect2, varscan2
- ZNF618 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.41); catalogued as rs775436175; called by muse, mutect2, varscan2
- ADAMTS2 | c.2560G>A p.V854M | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- BLOC1S6 | c.131T>A p.I44K | Missense Mutation (SNP) | VAF 80/133 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CACNA1D | c.1703G>A p.C568Y (on ENST00000350061 / NM_001128840.3; = p.C588Y on NM_000720.4) | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.438); called by muse, mutect2
- CACNA1G | c.1641del p.G548Vfs*16 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | called by mutect2, pindel
- CADM1 | c.993dup p.D332Rfs*34 | Frame Shift Ins (INS) | VAF 16/56 reads (29%) | called by mutect2, pindel
- CFAP58 | c.1127G>A p.R376K | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DPYSL4 | c.439A>C p.S147R | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.031); called by muse, mutect2
- GALNT15 | c.1513T>C p.F505L | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HTT | c.3419A>G p.Q1140R | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ITGA5 | c.2868G>T p.Q956H | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- KDM3A | c.3091C>A p.P1031T | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, mutect2
- KIF1C | c.269A>G p.N90S | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- NUP188 | c.1198C>A p.Q400K | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.93); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- PTGDR2 | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- RTL9 | c.1941C>G p.D647E | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- TG | c.3548A>G p.Q1183R | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.52); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- THEMIS | c.328A>C p.S110R | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- TMED4 | c.167A>C p.Y56S | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- TRIM9 | c.1117G>A p.V373M | Missense Mutation (SNP) | VAF 70/123 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ZSCAN25 | c.1153A>G p.T385A | Missense Mutation (SNP) | VAF 11/276 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- ACSBG1 | c.2139T>A p.G713= | Silent (SNP) | VAF 27/121 reads (22%) | called by muse, mutect2, varscan2
- CHRNA3 | c.1266C>T p.S422= | Silent (SNP) | VAF 91/289 reads (31%) | catalogued as rs74864179; called by muse, mutect2, varscan2
- FER1L5 | c.387G>A p.E129= | Silent (SNP) | VAF 38/97 reads (39%) | catalogued as rs1027452564; called by muse, mutect2, varscan2
- GDPD5 | c.552C>G p.A184= | Silent (SNP) | VAF 5/95 reads (5%) | called by muse, mutect2
- HIP1R | c.1515G>A p.L505= | Silent (SNP) | VAF 11/121 reads (9%) | called by muse, mutect2
- MGRN1 | c.882C>T p.R294= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as rs773347043; called by muse, mutect2, varscan2
- NCKAP5L | c.3837G>A p.P1279= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs768830633; called by muse, mutect2, varscan2
- NOTUM | c.1341C>T p.P447= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as rs1028790061; called by muse, mutect2, varscan2
- OGDHL | c.1876C>T p.L626= | Silent (SNP) | VAF 5/42 reads (12%) | called by muse, mutect2, varscan2
- PRDM5 | c.306A>T p.G102= | Silent (SNP) | VAF 34/65 reads (52%) | called by muse, mutect2, varscan2
- PTPRZ1 | c.4068T>G p.A1356= | Silent (SNP) | VAF 16/142 reads (11%) | called by muse, mutect2, varscan2
- TMEM54 | c.345C>T p.S115= | Silent (SNP) | VAF 14/156 reads (9%) | called by muse, mutect2
- ZNF546 | c.477G>A p.G159= | Silent (SNP) | VAF 21/163 reads (13%) | called by muse, mutect2
- AC139495.2 | n.948G>C | RNA (SNP) | VAF 141/803 reads (18%) | catalogued as rs1400098971; called by muse, mutect2, varscan2
- ADGRD1 | c.*1046C>T | 3'UTR (SNP) | VAF 30/145 reads (21%) | catalogued as rs931388168; called by muse, mutect2, varscan2
- AQP4 | c.*2414T>C | 3'UTR (SNP) | VAF 3/49 reads (6%) | catalogued as COSV101270493; called by muse, mutect2
- CBX7 | c.*654C>T | 3'UTR (SNP) | VAF 6/55 reads (11%) | called by muse, mutect2, varscan2
- CCSAP | c.*1759A>C | 3'UTR (SNP) | VAF 40/43 reads (93%) | catalogued as rs1331625645; called by muse, mutect2, varscan2
- CCSER1 | c.*878T>G | 3'UTR (SNP) | VAF 36/78 reads (46%) | called by muse, mutect2, varscan2
- CHD5 | c.*2598G>T | 3'UTR (SNP) | VAF 36/85 reads (42%) | called by muse, mutect2, varscan2
- CHST9 | c.241-8509A>G | Intron (SNP) | VAF 30/62 reads (48%) | called by muse, mutect2, varscan2
- EEF1E1 | c.-16G>A | 5'UTR (SNP) | VAF 36/86 reads (42%) | catalogued as COSV101121272; called by muse, mutect2, varscan2
- EMC10 | c.*636T>C | 3'UTR (SNP) | VAF 28/104 reads (27%) | called by muse, mutect2
- ERMP1 | c.*2467A>C | 3'UTR (SNP) | VAF 35/136 reads (26%) | called by muse, mutect2, varscan2
- GABARAPL2 | c.*126C>T | 3'UTR (SNP) | VAF 10/65 reads (15%) | catalogued as rs1357933522; called by muse, mutect2, varscan2
- GLCCI1 | c.*455A>G | 3'UTR (SNP) | VAF 46/107 reads (43%) | called by muse, mutect2, varscan2
- HDLBP | c.*22T>C | 3'UTR (SNP) | VAF 61/128 reads (48%) | called by muse, mutect2, varscan2
- IER5 | c.*38G>A | 3'UTR (SNP) | VAF 16/45 reads (36%) | called by muse, mutect2, varscan2
- ITCH | chr20:34510056 A>C | 3'Flank (SNP) | VAF 30/98 reads (31%) | called by muse, mutect2, varscan2
- KIAA1671 | c.*1827C>T | 3'UTR (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2, varscan2
- KIF13A | c.*186C>A | 3'UTR (SNP) | VAF 58/115 reads (50%) | called by muse, mutect2, varscan2
- METTL4 | c.*924A>G | 3'UTR (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2
- MINAR1 | c.*911T>A | 3'UTR (SNP) | VAF 103/151 reads (68%) | called by muse, mutect2, varscan2
- MYCL | c.*1019G>A | 3'UTR (SNP) | VAF 6/109 reads (6%) | catalogued as rs1407603549; called by muse, mutect2
- NLGN1 | c.*1401G>A | 3'UTR (SNP) | VAF 14/111 reads (13%) | catalogued as rs935100637; called by muse, mutect2, varscan2
- OLFM4 | c.*547G>A | 3'UTR (SNP) | VAF 22/97 reads (23%) | catalogued as rs1262071880; called by muse, mutect2, varscan2
- PER3 | c.*152C>T | 3'UTR (SNP) | VAF 45/85 reads (53%) | called by muse, mutect2, varscan2
- RASAL2 | c.*1569G>C | 3'UTR (SNP) | VAF 14/22 reads (64%) | called by muse, mutect2
- SMYD1 | c.*850del | 3'UTR (DEL) | VAF 8/81 reads (10%) | called by mutect2, pindel
- SNORD114-24 | n.11G>A | RNA (SNP) | VAF 10/118 reads (8%) | catalogued as rs1295588088; called by muse, mutect2
- SNX29P2 | n.291G>A | RNA (SNP) | VAF 17/36 reads (47%) | called by muse, mutect2, varscan2
- SPEN | c.*422G>A | 3'UTR (SNP) | VAF 35/94 reads (37%) | called by muse, mutect2, varscan2
- TCP11L1 | c.*813_*823delinsG | 3'UTR (DEL) | VAF 8/61 reads (13%) | called by pindel, varscan2*
- TMEM140 | c.-72T>C | 5'UTR (SNP) | VAF 25/66 reads (38%) | called by muse, mutect2, varscan2
- TRIM66 | c.*2906G>A | 3'UTR (SNP) | VAF 28/88 reads (32%) | called by muse, mutect2, varscan2
- TTC23 | c.*1266G>A | 3'UTR (SNP) | VAF 9/30 reads (30%) | catalogued as rs1260563075; called by muse, mutect2, varscan2
- UBC | chr12:124914825 T>G | 5'Flank (SNP) | VAF 29/54 reads (54%) | called by muse, varscan2
- UBE2D4 | c.*610G>A | 3'UTR (SNP) | VAF 7/120 reads (6%) | called by muse, mutect2
- UBE2J1 | c.*1160T>C | 3'UTR (SNP) | VAF 8/63 reads (13%) | called by muse, mutect2, varscan2
- VANGL1 | chr1:115693219 G>A | 3'Flank (SNP) | VAF 61/115 reads (53%) | catalogued as rs913399331; called by muse, mutect2, varscan2
- VEGFC | c.-308C>T | 5'UTR (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- ZNF322P1 | n.789T>C | RNA (SNP) | VAF 26/81 reads (32%) | called by mutect2, varscan2
- ZNF879 | c.*379dup | 3'UTR (INS) | VAF 48/155 reads (31%) | called by mutect2, pindel, varscan2
